Somatic mutation profile of tumor specimen TCGA-VF-A8AB-01A (aliquot TCGA-VF-A8AB-01A-31D-A435-10) from TCGA case TCGA-VF-A8AB, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 31.9 years (11,659 days).
Specimen TCGA-VF-A8AB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ca8a58d-76fd-4900-a62c-74cafc0f8460.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VF-A8AB-10A (Blood Derived Normal), aliquot TCGA-VF-A8AB-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cab444c3-aa24-42f6-b3ed-c4fa5ebe721a

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Splice Site 1, 5'UTR 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATF5 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.792); catalogued as rs750945865; called by muse, mutect2, varscan2
- HOXB2 | c.272del p.P91Rfs*8 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as rs761024113; called by mutect2, pindel, varscan2
- KNOP1 | c.979A>G p.I327V | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as COSV54929814; called by muse, mutect2, varscan2
- PKD1 | c.7479C>G p.F2493L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752349510; called by muse, mutect2, varscan2
- SART3 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs771178583; called by muse, mutect2, varscan2
- SLC38A11 | c.370-1G>C p.X124_splice (on ENST00000409149 / NM_001351539.1; = p.X102_splice on NM_173512.2) | Splice Site (SNP) | VAF 5/48 reads (10%) | catalogued as COSV58056353; called by muse, mutect2, varscan2
- TMEM120A | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.254); catalogued as rs782820867; called by muse, mutect2
- ANKRD11 | c.7274A>T p.D2425V | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ANKRD11 | c.7273G>T p.D2425Y | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- DOP1A | c.3907G>T p.A1303S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MICAL3 | c.5756_5761del p.R1919_E1920del | In Frame Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel, varscan2
- PHKB | c.1357C>G p.L453V | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- RAB3GAP1 | c.2315A>T p.K772I | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SPNS3 | c.670G>T p.V224F | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CHAF1A | c.591C>T p.G197= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as rs188842259; called by muse, mutect2
- NPR3 | c.381G>A p.K127= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV99423720; called by muse, mutect2, varscan2
- ZAN | c.8376G>A p.T2792= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as rs200657807; called by muse, mutect2, varscan2
- PPP1R3B | c.-2C>T | 5'UTR (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2
